Somatic mutation profile of tumor specimen TCGA-EY-A2OP-01A (aliquot TCGA-EY-A2OP-01A-11D-A19Y-09) from TCGA case TCGA-EY-A2OP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 63.2 years (23,090 days).
Specimen TCGA-EY-A2OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a5dfed6-ff03-4894-b300-93403e597580.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A2OP-10A (Blood Derived Normal), aliquot TCGA-EY-A2OP-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebf21402-2d25-41e5-9f6b-715376b3ed4c

The open-access MAF lists 550 somatic variants for this specimen: 423 protein-altering or splice-affecting, 111 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 111, Frame Shift Del 100, Nonsense Mutation 19, Frame Shift Ins 16, Intron 7, Splice Site 7, RNA 6, In Frame Del 6, 3'Flank 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR1A | c.1511G>A p.W504* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as rs878854664, COSV100923696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COQ8A | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs763311061, COSV100825786; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 63/68 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GBA | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs374306700, CM043285; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389del p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 76/112 reads (68%) | catalogued as rs121913292, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB4 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55944193; called by mutect2, varscan2
- ABHD16B | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs772049053, COSV99410849; called by muse, mutect2, varscan2
- ACSM2B | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313047; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163901568, COSV100866637; called by muse, mutect2
- ADAMTS12 | c.2828T>C p.L943P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100711543; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3091C>T p.Q1031* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV101002025; called by muse, mutect2, varscan2
- ADAR | c.2401C>A p.R801S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99426565; called by muse, mutect2, varscan2
- ADGRB2 | c.2945T>C p.L982P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99926765; called by muse, varscan2
- AEBP2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99857975; called by muse, mutect2, varscan2
- AFF2 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99665766; called by muse, mutect2, varscan2
- AFF4 | c.2222del p.K741Rfs*101 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as COSV54794218; called by mutect2, pindel, varscan2
- AHNAK2 | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.693); catalogued as COSV100318647; called by muse, mutect2, varscan2
- AJM1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1429413360, COSV99915856; called by muse, mutect2
- AKAP6 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.36); catalogued as rs770309860, COSV99803611; called by muse, varscan2
- AKAP8 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1293704113, COSV99512027; called by muse, mutect2, varscan2
- ALOX15B | c.104del p.P35Hfs*21 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs747925269; called by mutect2, pindel, varscan2
- ANK2 | c.3799G>A p.G1267R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52164532; called by muse, mutect2, varscan2
- ANTKMT | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs370792065; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AOC3 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV99520351; called by muse, mutect2, varscan2
- APAF1 | c.2996G>T p.R999M (on ENST00000551964 / NM_181861.2; = p.R945M on NM_001160.3) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.436); catalogued as COSV100244126; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs758608743; called by mutect2, varscan2
- ARNT | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV99648919; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | catalogued as rs753865255; called by mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs761154268; called by mutect2, varscan2
- ATP8B4 | c.1175A>T p.D392V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467015; called by muse, mutect2, varscan2
- BAG6 | c.3028C>T p.R1010W (on ENST00000676571; = p.R963W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs758960107, COSV52988646; called by muse, mutect2, varscan2
- BCAR1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV50781513; called by muse, mutect2, varscan2
- BCR | c.1038_1040del p.S347del | In Frame Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs772823202; called by pindel, varscan2
- BDKRB1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV53706659, COSV99388004; called by muse, mutect2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BTBD2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs570197197, COSV99724923; called by muse, mutect2, varscan2
- BTN3A3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0.178); catalogued as rs746357036, COSV99765019; called by muse, mutect2, varscan2
- C1QTNF2 | c.457del p.R153Vfs*49 (on ENST00000393975; = p.R108Vfs*49 on NM_031908.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs772822571, COSV67432492; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN12 | c.1735C>A p.L579M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV99399662; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC82 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99567501; called by muse, mutect2, varscan2
- CD1C | c.715T>C p.W239R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761837821, COSV100939435; called by muse, mutect2, varscan2
- CD3E | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV100689069; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs762194001; called by mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs753353408; called by mutect2, varscan2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs750494120; called by mutect2, pindel, varscan2
- CEP152 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100359056; called by muse, mutect2, varscan2
- CHCHD5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs201729327, COSV61424296; called by muse, mutect2, varscan2
- CHCHD7 | c.93C>A p.N31K (on ENST00000355315 / NM_001011671.3; = p.N43K on NM_024300.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV100374707, COSV58132169; called by muse, mutect2, varscan2
- CIAO3 | c.1193-1G>T p.X398_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs754183985, COSV52402694; called by muse, mutect2, varscan2
- CLCN1 | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100578418; called by muse, mutect2, varscan2
- CNN1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs748000390, COSV52947589; called by muse, mutect2, varscan2
- COL26A1 | c.1273C>T p.L425F (on ENST00000313669 / NM_001278563.3; = p.L423F on NM_133457.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100561734, COSV100561971; called by muse, mutect2, varscan2
- COL5A3 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.307); catalogued as rs774594724, COSV53406624, COSV53414403; called by muse, mutect2, varscan2
- COL6A3 | c.8744C>T p.A2915V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs751532649, COSV55080470; ClinVar: uncertain significance; called by muse, mutect2
- COL6A6 | c.6226A>G p.T2076A | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.058); catalogued as rs1384183895, COSV100650793; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CREBBP | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778882385, COSV52115701; called by muse, mutect2, varscan2
- CROCC | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs367650777; called by muse, mutect2, varscan2
- CSRNP1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56187239; called by muse, mutect2, varscan2
- CTCF | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50471256, COSV99866409; called by muse, mutect2, varscan2
- CTDSP2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1270875191, COSV66080015; called by muse, mutect2, varscan2
- CTSC | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99910913; called by muse, mutect2, varscan2
- CTSO | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV101467879; called by muse, mutect2, varscan2
- CUL9 | c.6922-2A>C p.X2308_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99335897; called by muse, mutect2, varscan2
- DAZAP1 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV99245435; called by muse, mutect2, varscan2
- DBX1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as COSV99910296; called by muse, mutect2
- DCAF13 | c.1040T>C p.M347T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.122); catalogued as COSV99885578; called by muse, mutect2, varscan2
- DCHS1 | c.8423A>C p.E2808A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100197685; called by muse, mutect2, varscan2
- DCTN1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV100721040; called by muse, mutect2, varscan2
- DENND1A | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs776432167, COSV101010340, COSV101010771; called by muse, mutect2, varscan2
- DENND2C | c.2747G>A p.R916Q (on ENST00000393274 / NM_001256404.2; = p.R859Q on NM_198459.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs139442561; called by mutect2, varscan2
- DGLUCY | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs766574192, COSV99824640; called by muse, mutect2, varscan2
- DHRSX | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs372205535, COSV100585985; called by muse, mutect2
- DIP2C | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99793365; called by muse, mutect2, varscan2
- DMRT1 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66519329; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs35482889; called by mutect2, varscan2
- DPPA2 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101524791; called by muse, mutect2, varscan2
- DPY19L2 | c.451-2del p.X151_splice | Splice Site (DEL) | VAF 12/32 reads (38%) | catalogued as rs202064990, COSV60543692; called by mutect2, pindel
- DSCAML1 | c.5914C>T p.R1972* (on ENST00000321322; = p.R1912* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs1450422367, COSV100355028; called by muse, mutect2, varscan2
- DSP | c.8537G>A p.R2846Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs780766289, COSV100673048; called by muse, mutect2, varscan2
- DTNA | c.1400A>G p.D467G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99314599; called by muse, mutect2, varscan2
- DUOX1 | c.3403T>A p.S1135T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as COSV100368361; called by muse, mutect2, varscan2
- DYNC1H1 | c.13303G>A p.V4435I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs767195767, COSV100795278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEA1 | c.2903G>A p.S968N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100468336; called by muse, mutect2, varscan2
- EFL1 | c.2199A>C p.Q733H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99188186; called by muse, mutect2, varscan2
- EIF4G2 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV101151078; called by muse, mutect2, varscan2
- ELL2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765162118, COSV52980994; called by muse, mutect2, varscan2
- EMILIN1 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99566495; called by muse, mutect2
- EOGT | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99809097; called by muse, mutect2, varscan2
- EP400 | c.7760C>T p.T2587M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747711566, COSV57769216; called by muse, mutect2, varscan2
- EPHA1 | c.335del p.G112Efs*34 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV51970381, COSV51976424; called by mutect2, pindel, varscan2
- ERN1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs773561085, COSV101458525; called by muse, mutect2, varscan2
- EXPH5 | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs1024384240, COSV99762053; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM135B | c.2252G>T p.S751I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99426629; called by muse, mutect2, varscan2
- FAM178B | c.1708C>A p.L570M (on ENST00000490605 / NM_001122646.3; = p.L10M on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.988); catalogued as COSV100014459; called by muse, mutect2, varscan2
- FASN | c.1428G>T p.E476D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100148226; called by muse, mutect2, varscan2
- FBXW8 | c.1429G>T p.A477S (on ENST00000309909; = p.A515S on NM_012174.1) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs139120742, COSV99997945; called by muse, mutect2, varscan2
- FCAMR | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747848205, COSV61366773; called by muse, mutect2, varscan2
- FEZF1 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100484499, COSV100484539; called by muse, mutect2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLG | c.9325A>G p.T3109A | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100912000; called by muse, mutect2, varscan2
- FLRT2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58141830; called by muse, mutect2, varscan2
- FLT3LG | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99201347; called by muse, mutect2, varscan2
- FRAS1 | c.8793G>T p.K2931N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99355099; called by muse, mutect2, varscan2
- FRMD6 | c.1004G>A p.R335Q (on ENST00000344768 / NM_001267046.2; = p.R327Q on NM_152330.4) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as rs1016945695, COSV61089462; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs1348158626; called by mutect2, varscan2
- FTSJ1 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99191443; called by muse, mutect2, varscan2
- FXR2 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs377561745, COSV100002175; called by muse, mutect2, varscan2
- FZD2 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100190746; called by muse, mutect2, varscan2
- GAREM1 | c.2272G>A p.G758R (on ENST00000269209 / NM_001242409.2; = p.G757R on NM_022751.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as COSV99331228; called by muse, mutect2, varscan2
- GEMIN5 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1410641008, COSV99594237; called by muse, mutect2
- GEMIN5 | c.2812A>C p.T938P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as COSV99594238; called by muse, mutect2, varscan2
- GGA3 | c.619C>T p.R207W (on ENST00000537686 / NM_138619.4; = p.R174W on NM_014001.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372653160; called by muse, mutect2, varscan2
- GGN | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV99287644; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs763147690; called by mutect2, varscan2
- GPATCH4 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs557781070, COSV100576985; called by muse, mutect2, varscan2
- GPR153 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471356056, COSV64938571; called by muse, mutect2, varscan2
- GPRASP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781232292, COSV100851060; called by muse, mutect2, varscan2
- GPRASP1 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV100851061; called by muse, mutect2, varscan2
- GRIA1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752447548, COSV53605030; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GRM8 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs199601760; called by muse, mutect2, varscan2
- GRM8 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100285200; called by muse, mutect2, varscan2
- HEATR1 | c.4957C>T p.Q1653* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100857768; called by muse, mutect2, varscan2
- HEATR4 | c.1678A>G p.N560D | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100620577; called by muse, mutect2, varscan2
- HELZ | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as rs202142788; called by muse, mutect2, varscan2
- HELZ2 | c.7576G>A p.A2526T (on ENST00000467148 / NM_001037335.2; = p.A1957T on NM_033405.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs573248815, COSV100918800; called by muse, mutect2, varscan2
- HERC2 | c.9410C>T p.T3137M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs779163278, COSV99876176; called by muse, mutect2, varscan2
- HHIPL1 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100415321; called by muse, mutect2, varscan2
- HK3 | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs192416700, COSV99459162; called by muse, mutect2
- HKDC1 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777856618, COSV63577944; called by muse, mutect2, varscan2
- HOXA2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs187162003, COSV99761378; called by muse, mutect2, varscan2
- HSPG2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs1033676362, COSV101021077; called by muse, mutect2, varscan2
- HTT | c.9329G>T p.R3110M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100751138; called by muse, mutect2, varscan2
- HYDIN | c.6914A>G p.E2305G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99993507; called by muse, mutect2, varscan2
- IKZF1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1270036178, COSV58785900; called by muse, mutect2, varscan2
- IRF8 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99236772; called by muse, mutect2, varscan2
- ITFG1 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV100068227; called by muse, mutect2, varscan2
- ITGA7 | c.1721C>T p.A574V (on ENST00000555728; = p.A530V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs200267194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR2 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV101190121; called by muse, mutect2, varscan2
- ITPRID1 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs1362510095, COSV100087279; called by muse, mutect2, varscan2
- JADE2 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99253571; called by muse, mutect2, varscan2
- JPH1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60608366; called by muse, mutect2
- KANSL1 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as COSV52264743; called by muse, mutect2, varscan2
- KATNAL2 | c.412G>T p.G138W (on ENST00000356157 / NM_001353899.1; = p.G66W on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99797669; called by muse, mutect2, varscan2
- KDM2A | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs371369134; called by muse, mutect2, varscan2
- KDM6B | c.4783C>T p.R1595C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99642117; called by muse, mutect2
- KDM8 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99619891; called by muse, mutect2, varscan2
- KIRREL1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs148744748; called by muse, mutect2, varscan2
- KLHL34 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101069859, COSV65280313; called by muse, mutect2, varscan2
- KPRP | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); catalogued as rs773581259, COSV64222707; called by muse, mutect2, varscan2
- KRT33A | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV99144987; called by muse, mutect2, varscan2
- KRT8 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV53179800; called by muse, mutect2, varscan2
- KRTAP19-7 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100603219; called by muse, mutect2, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs782221297; called by mutect2, varscan2
- LATS1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.828); catalogued as rs763594987, COSV99486518; called by muse, mutect2, varscan2
- LDB3 | c.1602del p.T535Pfs*30 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV53943506, COSV53951508; called by mutect2, pindel, varscan2
- LHPP | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs763505137, COSV64331710; called by muse, mutect2, varscan2
- LMOD3 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101342023; called by muse, mutect2, varscan2
- LMTK2 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs749372914, COSV99807513; called by muse, mutect2, varscan2
- LTBP1 | c.3275G>A p.G1092E (on ENST00000404816 / NM_206943.4; = p.G766E on NM_000627.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766868611, COSV99698663; called by muse, mutect2, varscan2
- LYN | c.392del p.F131Sfs*4 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | catalogued as COSV70205714; called by mutect2, pindel, varscan2
- MAGEB1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs373877042, COSV66775377; called by muse, mutect2, varscan2
- MAP3K19 | c.2161dup p.T721Nfs*13 | Frame Shift Ins (INS) | VAF 20/41 reads (49%) | catalogued as rs771955948; called by mutect2, varscan2
- MAP3K3 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100675621; called by muse, mutect2, varscan2
- MAP6 | c.1526A>G p.H509R | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100496857; called by muse, varscan2
- MBP | c.529C>T p.R177C (on ENST00000355994 / NM_001025101.2; = p.R44C on NM_002385.3) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs748450291, COSV100592736, COSV62828381; called by muse, mutect2, varscan2
- MCM6 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99919326; called by muse, mutect2, varscan2
- MED13L | c.5611G>A p.A1871T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV99929883; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MELTF | c.1092del p.Y365Tfs*54 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs748010566; called by mutect2, pindel, varscan2
- MGAM | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1163875284, COSV72073816; called by muse, mutect2, varscan2
- MGAT3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100362025; called by muse, mutect2, varscan2
- MKI67 | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV100896901; called by muse, mutect2, varscan2
- MLXIP | c.2629C>A p.L877I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100039061; called by muse, mutect2, varscan2
- MMEL1 | c.2168G>T p.W723L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56522703, COSV99984342; called by muse, mutect2, varscan2
- MRC2 | c.673T>C p.W225R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316653; called by muse, mutect2, varscan2
- MTMR3 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100071263; called by muse, mutect2, varscan2
- MTTP | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV99645486; called by muse, mutect2, varscan2
- MUC16 | c.23136dup p.S7713Lfs*40 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | catalogued as rs1568814554; called by mutect2, varscan2
- MUC5AC | c.969dup p.L324Vfs*9 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | catalogued as rs1227165697; called by mutect2, pindel, varscan2
- MVP | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.443); catalogued as COSV100651696; called by muse, mutect2, varscan2
- MYH11 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750974235, COSV55544954; called by muse, mutect2
- MYO1A | c.2972C>T p.T991M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs200914927; called by muse, mutect2, varscan2
- NBAS | c.5089C>T p.R1697C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs775517783, COSV55718790; called by muse, varscan2
- NBEA | c.6200G>A p.R2067H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755782734, COSV59765425; called by muse, mutect2, varscan2
- NCAPD3 | c.3278_3279del p.K1093Rfs*17 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs759303536; called by mutect2, pindel, varscan2
- NCK2 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as rs767975664, COSV51895044; called by muse, mutect2, varscan2
- NCOR1 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV51970277; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel, varscan2
- NDST3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1469620941, COSV56613923; called by muse, mutect2, varscan2
- NEBL | c.2138A>C p.N713T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101009313; called by muse, mutect2, varscan2
- NFATC1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs372492742; called by muse, mutect2, varscan2
- NFATC3 | c.2068del p.S690Afs*12 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as COSV60473781; called by mutect2, pindel, varscan2
- NFKBIZ | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs150091528, COSV58199423; called by muse, mutect2, varscan2
- NGRN | c.332T>A p.F111Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100517993; called by muse, mutect2, varscan2
- NLRC5 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as rs531478769, COSV99346693; called by muse, mutect2, varscan2
- NOS1AP | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs868398500, COSV100723552; called by muse, mutect2
- NPEPL1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.828); catalogued as rs369185988; called by muse, mutect2, varscan2
- NSD1 | c.6581C>T p.S2194F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100729722; called by muse, mutect2, varscan2
- NSG1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.537); catalogued as rs755840500, COSV101207956; called by muse, mutect2, varscan2
- NT5DC1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.129); catalogued as rs757924218, COSV100127150, COSV100127238; called by muse, mutect2, varscan2
- NUCB1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); catalogued as rs369477250; called by muse, mutect2, varscan2
- NVL | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs760493438, COSV99894976; called by muse, mutect2, varscan2
- OPA3 | c.143-1G>A p.X48_splice | Splice Site (SNP) | VAF 46/104 reads (44%) | catalogued as rs1333432889, COSV99841120; called by muse, mutect2, varscan2
- OPCML | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100104009; called by muse, mutect2, varscan2
- OR10J5 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100604804; called by muse, mutect2, varscan2
- OR52N4 | c.834T>G p.I278M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.756); catalogued as COSV100421744; called by muse, mutect2, varscan2
- OR9G4 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310172988, COSV100265236; called by muse, mutect2
- ORM1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs139631990, COSV52281569; called by muse, mutect2, varscan2
- P2RY8 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs757722742, COSV101184089, COSV67177063; called by muse, mutect2, varscan2
- PAPPA | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV60290279; called by muse, mutect2, varscan2
- PARP4 | c.1915-2A>G p.X639_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV67963941; called by muse, varscan2
- PATZ1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99315579; called by muse, mutect2, varscan2
- PBRM1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56267627, COSV99970439; called by muse, mutect2, varscan2
- PCDHB12 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53397320; called by muse, mutect2, varscan2
- PCDHGB5 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs756646382; called by muse, mutect2, varscan2
- PDE1C | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs770014076, COSV100373540; called by muse, mutect2, varscan2
- PHF12 | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99256131; called by muse, mutect2, varscan2
- PHIP | c.1050del p.F350Lfs*32 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs1473613198, CD1513763; called by mutect2, pindel, varscan2
- PIK3R5 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777086538, COSV52655561; called by muse, mutect2, varscan2
- PKD1 | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.125); catalogued as COSV99236848; called by muse, mutect2, varscan2
- PKHD1 | c.5009T>C p.L1670S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100584255; called by muse, mutect2, varscan2
- PLEKHG1 | c.3467A>G p.N1156S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); catalogued as COSV100651820; called by muse, mutect2, varscan2
- PLPP2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/10 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV99514793; called by muse, mutect2, varscan2
- PNPO | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310951750, COSV99846557; called by muse, mutect2, varscan2
- POF1B | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99426443; called by muse, mutect2, varscan2
- PORCN | c.1003G>A p.A335T (on ENST00000326194 / NM_203475.3; = p.A324T on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV100400522; called by muse, mutect2, varscan2
- PPP1R13B | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99161452; called by muse, mutect2, varscan2
- PRDM11 | c.799C>A p.L267M (on ENST00000530656 / NM_001359633.1; = p.L233M on NM_001256695.1) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV99771036; called by muse, mutect2, varscan2
- PRDM9 | c.1245C>A p.N415K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV99691030; called by muse, mutect2, varscan2
- PRORP | c.1413del p.F471Lfs*30 | Frame Shift Del (DEL) | VAF 35/78 reads (45%) | catalogued as rs766680749; called by mutect2, pindel, varscan2
- PRPF6 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99412632; called by muse, mutect2
- PRPF8 | c.2291G>T p.G764V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517811, COSV59263542; called by muse, mutect2, varscan2
- PRSS22 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99361962; called by muse, mutect2, varscan2
- PSMA4 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs751350183, COSV50384947; called by muse, mutect2, varscan2
- PSMD10 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs376151499, COSV99480739; called by muse, mutect2, varscan2
- PTCD1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99464411; called by muse, mutect2, varscan2
- PTF1A | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV100919606; called by muse, mutect2
- PTP4A3 | c.412C>T p.R138C (on ENST00000329397; = p.R113C on NM_007079.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as rs145157893, COSV61472499; called by muse, mutect2, varscan2
- PTPRG | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs200002839, COSV99876560; called by muse, mutect2, varscan2
- PTPRM | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100159617; called by muse, mutect2, varscan2
- PTPRO | c.2849T>C p.L950P (on ENST00000281171 / NM_030667.3; = p.L922P on NM_002848.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99841464; called by muse, mutect2, varscan2
- PUM3 | c.1233T>G p.I411M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV101193223; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAG1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs557360812, COSV55028378; called by muse, mutect2, varscan2
- RASGRF1 | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101174711; called by muse, mutect2
- RC3H2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777562155, COSV59010468; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF150 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV100154001; called by muse, mutect2, varscan2
- RNF43 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as COSV101348520; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RRP12 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1286880149, COSV59667099; called by muse, mutect2, varscan2
- RYR2 | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368040638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD11 | c.81del p.R28Gfs*16 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs1386232016; called by mutect2, pindel, varscan2
- SATB2 | c.1340T>C p.M447T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs749656722, COSV99612302; called by muse, varscan2
- SCAF8 | c.1612A>G p.K538E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100914253; called by muse, mutect2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs757259031; called by mutect2, varscan2
- SCN11A | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758597298, COSV56577794; ClinVar: uncertain significance; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA5B | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99531677; called by muse, mutect2, varscan2
- SEMA6D | c.2405G>A p.R802K (on ENST00000316364 / NM_153618.2; = p.R740K on NM_020858.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.688); catalogued as rs1412093121, COSV100317443; called by muse, mutect2, varscan2
- SETD2 | c.4003C>T p.R1335C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1216047088, COSV57448285; called by muse, mutect2, varscan2
- SGSM1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749576223, COSV68510943; called by muse, mutect2, varscan2
- SHKBP1 | c.1339T>C p.C447R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99199232; called by muse, mutect2, varscan2
- SI | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1203105060, COSV100016792; called by mutect2, varscan2
- SIGLEC7 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs777572884, COSV58315195; called by muse, mutect2, varscan2
- SIX2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57390076; called by muse, mutect2, varscan2
- SLC39A4 | c.1640C>T p.A547V (on ENST00000301305 / NM_001374839.1; = p.A522V on NM_017767.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); catalogued as COSV99433645; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1466680694; called by mutect2, pindel
- SMC6 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs763328076, COSV100704664; called by muse, mutect2, varscan2
- SMG6 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99558611; called by muse, mutect2, varscan2
- SMTN | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1334467518, COSV60782661; called by muse, mutect2, varscan2
- SOWAHD | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100673110, COSV59649759; called by muse, mutect2, varscan2
- SPEN | c.2875A>G p.K959E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV101005526; called by muse, mutect2, varscan2
- SPEN | c.6313del p.A2105Lfs*33 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV65367511; called by pindel, varscan2
- SPTA1 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100935424; called by mutect2, varscan2
- SRPX2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs770689659, COSV100884056; called by muse, mutect2, varscan2
- SRRM2 | c.7808G>A p.R2603Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV51940646; called by muse, mutect2, varscan2
- STAB2 | c.4594C>T p.Q1532* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV66349559; called by muse, mutect2, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs761897392; called by mutect2, pindel, varscan2
- STEAP2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748899164, COSV55292913; called by muse, mutect2, varscan2
- STOML1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1221349536, COSV57552589; called by muse, mutect2, varscan2
- STYXL2 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs573913763, COSV99068450; called by muse, mutect2, varscan2
- SYT1 | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.281); catalogued as COSV99696972; called by muse, mutect2
- TAF1 | c.3169C>G p.L1057V (on ENST00000373790 / NM_138923.4; = p.L1078V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52111906; called by muse, mutect2, varscan2
- TAF6 | c.720+2T>C p.X240_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100612841; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBPL2 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99905514; called by muse, mutect2, varscan2
- TCP1 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100365042; called by muse, mutect2, varscan2
- TEX10 | c.1489+2T>C p.X497_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100887940; called by muse, mutect2, varscan2
- THAP6 | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as rs1403413814, COSV61162664; called by muse, mutect2, varscan2
- TJAP1 | c.962C>T p.P321L (on ENST00000372445 / NM_001146016.1; = p.P311L on NM_080604.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs780017622, COSV99446630; called by muse, mutect2, varscan2
- TLR7 | c.1463A>G p.N488S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV101028088; called by muse, mutect2, varscan2
- TMC6 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs772282970, COSV59808821; called by muse, mutect2, varscan2
- TP53BP2 | c.1350G>T p.E450D (on ENST00000343537 / NM_001031685.3; = p.E321D on NM_005426.2) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100636756; called by muse, mutect2
- TPBG | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100869804; called by muse, mutect2, varscan2
- TPCN2 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99593849; called by muse, mutect2, varscan2
- TRMT2B | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100105617; called by muse, mutect2, varscan2
- TSPAN32 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV99478376; called by muse, mutect2, varscan2
- TTN | c.93553G>A p.A31185T (on ENST00000591111; = p.A23761T on NM_003319.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | PolyPhen possibly damaging (0.453); catalogued as COSV100625943; called by muse, mutect2, varscan2
- TXLNA | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009895; called by muse, mutect2, varscan2
- UACA | c.3055A>G p.S1019G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100537682; called by muse, mutect2, varscan2
- UACA | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100537684; called by muse, varscan2
- UEVLD | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293347; called by muse, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- URB2 | c.1802A>C p.K601T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99271736; called by muse, mutect2, varscan2
- USP25 | c.2123C>A p.A708D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV99584374; called by muse, mutect2, varscan2
- USP35 | c.1738T>C p.C580R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101489127; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs764735138; called by mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs572063854; called by mutect2, varscan2
- USP9X | c.6808C>T p.P2270S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV61068325; called by muse, mutect2, varscan2
- VDAC1 | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV99527309; called by muse, mutect2, varscan2
- VPS13C | c.901G>A p.A301T (on ENST00000644861 / NM_020821.3; = p.A258T on NM_017684.5) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1371065317, COSV99829812; called by muse, mutect2, varscan2
- VPS13D | c.13141C>T p.R4381* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs753795620, COSV99168003; called by muse, mutect2, varscan2
- WAPL | c.3425C>T p.T1142I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99556584; called by muse, mutect2, varscan2
- WASHC5 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764120080, COSV100573010; called by muse, mutect2, varscan2
- WDPCP | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99706486; called by muse, mutect2, varscan2
- WDR44 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.546); catalogued as COSV99561878; called by muse, mutect2, varscan2
- WDR88 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs777013462, COSV100866615; called by muse, mutect2, varscan2
- WNK1 | c.1748del p.K583Sfs*11 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs746484082; called by mutect2, varscan2
- WNK2 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99944132; called by muse, mutect2, varscan2
- WNT3A | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780065621, COSV99470044; called by muse, mutect2, varscan2
- WNT7A | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53196840, COSV99541635; called by muse, mutect2, varscan2
- WWP1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371650373; called by muse, mutect2, varscan2
- XKR7 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.95); catalogued as COSV101629293; called by muse, mutect2, varscan2
- XPO7 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99381934; called by muse, mutect2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs779864368; called by pindel, varscan2
- ZBTB46 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs767812969, COSV99829598; called by muse, mutect2, varscan2
- ZBTB9 | c.1070del p.G357Vfs*15 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as COSV67702478; called by mutect2, varscan2
- ZIM3 | c.1105G>T p.G369* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99518500; called by muse, mutect2, varscan2
- ZNF233 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100492339; called by muse, mutect2, varscan2
- ZNF284 | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV101399072, COSV69691640; called by muse, mutect2, varscan2
- ZNF287 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101209418; called by muse, mutect2, varscan2
- ZNF287 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs751257245, COSV101209420; called by muse, mutect2, varscan2
- ZNF572 | c.1398del p.K466Nfs*26 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as COSV100073727; called by mutect2, varscan2
- ZNF594 | c.1922A>G p.K641R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs750240586, COSV101280549; called by muse, mutect2, varscan2
- ZNF804B | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931660793, COSV100305554; called by muse, mutect2, varscan2
- ZNF878 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs368365331; called by muse, mutect2, varscan2
- ZSCAN22 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV100308471; called by muse, mutect2, varscan2
- ARHGEF9 | c.1052dup p.K352Efs*16 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- ARID1B | c.4109del p.P1370Qfs*65 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- ATAD5 | c.1262del p.K421Sfs*17 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- B4GAT1 | c.696del p.S233Afs*38 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- CUL4B | c.857dup p.L286Ffs*5 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- DDIAS | c.249del p.F83Lfs*31 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- DENND5B | c.2141dup p.N714Kfs*21 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2
- ENAM | c.588+1del | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- F13A1 | c.869dup p.S291Ifs*8 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- FAM184A | c.3338del p.L1113* | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- FAM187B | c.754del p.L252* | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- FDFT1 | c.1213_1214del p.S405Pfs*47 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by pindel, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- FLOT2 | c.532_533del p.D178Cfs*2 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by pindel, varscan2
- HGH1 | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.845); called by muse, varscan2
- HTT | c.7809del p.E2604Sfs*7 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- IFIT5 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV1-46 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- IGLV3-19 | c.157T>C p.W53R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- KIF21A | c.387del p.K129Nfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- KPNA2 | c.332_333dup p.I112Pfs*2 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, pindel
- KRT25 | c.425del p.N142Ifs*41 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- LRBA | c.6838del p.R2280Efs*37 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- MARK4 | c.1960del p.R654Gfs*9 (on ENST00000262891 / NM_001199867.2; = p.G681Afs*17 on NM_031417.4) | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- METTL2B | c.915del p.G306Vfs*10 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- MME | c.594dup p.V199Sfs*4 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- MUC2 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NECTIN3 | c.1158del p.K386Nfs*24 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- NEIL1 | c.785_787del p.C262del | In Frame Del (DEL) | VAF 18/38 reads (47%) | called by pindel, varscan2
- NID2 | c.133del p.D45Tfs*15 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- NIPA1 | c.292dup p.L98Pfs*47 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- NSD3 | c.3289del p.R1097Afs*19 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- NXF3 | c.285dup p.P96Tfs*31 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- OR4S2 | c.10dup p.I4Nfs*6 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- PDGFB | c.584del p.G195Vfs*14 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- PHF23 | c.366dup p.D123Rfs*7 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- PIK3C2G | c.745del p.C249Afs*4 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.3960_3963del p.C1320* (on ENST00000414982 / NM_001166111.2; = p.C1272* on NM_006702.5) | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.982del p.V328Cfs*5 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- PPARG | c.892del p.L298Cfs*38 (on ENST00000287820 / NM_015869.5; = p.L268Cfs*38 on NM_005037.7) | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- PSME1 | c.463_465del p.K155del | In Frame Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- PTGDS | c.46del p.V16Cfs*64 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.3102del p.F1034Lfs*5 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- RBAK | c.818del p.K273Sfs*40 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.2728T>C p.S910P | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- RNF41 | c.589_591del p.N197del | In Frame Del (DEL) | VAF 24/47 reads (51%) | called by mutect2, pindel, varscan2
- RORA | c.290del p.F97Sfs*20 (on ENST00000335670 / NM_134261.3; = p.F122Sfs*20 on NM_002943.3) | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.261_263del p.L87_N88delinsF (on ENST00000265814 / NM_001198628.1; = p.L60_N61delinsF on NM_004349.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- SI | c.2025del p.F675Lfs*15 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- SLC24A3 | c.705del p.V236Ffs*7 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- SMC6 | c.41del p.N14Mfs*27 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- SNAPC1 | c.639del p.F213Lfs*7 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- STON2 | c.2051del p.L684* (on ENST00000649389 / NM_001366849.2; = p.L627* on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- TCHH | c.2851dup p.R951Kfs*14 | Frame Shift Ins (INS) | VAF 11/103 reads (11%) | called by mutect2, pindel, varscan2
- TENM3 | c.5753del p.P1918Rfs*60 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- THAP1 | c.300del p.P102Hfs*18 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- TNRC6A | c.2918del p.G973Dfs*47 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by pindel, varscan2
- TRIM35 | c.1403del p.G468Vfs*129 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- UTRN | c.9275_9277del p.D3092del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- WDR72 | c.2332del p.M778Cfs*9 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, varscan2
- WDR83 | c.460_461del p.D154Wfs*25 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- ABCA5 | c.4542C>T p.I1514= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs752011696, COSV101201257; called by muse, mutect2, varscan2
- ACP2 | c.1209C>T p.L403= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV99921817; called by muse, mutect2, varscan2
- ADAM28 | c.459T>C p.H153= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99739606; called by muse, mutect2, varscan2
- ADAMTS18 | c.2490T>C p.R830= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99273859; called by muse, mutect2, varscan2
- ADRA1A | c.1386C>T p.N462= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs201746874; called by muse, mutect2, varscan2
- AGAP6 | c.1917C>A p.T639= (on ENST00000374056 / NM_001365867.1; = p.T662= on NM_001077665.2) | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV100929133; called by muse, mutect2, varscan2
- ANKRD50 | c.2352C>A p.P784= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101539024; called by muse, mutect2, varscan2
- AOC1 | c.687G>A p.G229= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV100710912; called by muse, mutect2, varscan2
- ARSF | c.504T>C p.T168= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100839588; called by muse, mutect2, varscan2
- ASPHD1 | c.1104C>T p.D368= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1225961962, COSV100441826; called by muse, mutect2, varscan2
- ASPSCR1 | c.1455G>A p.A485= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs780920234, COSV60715879; called by muse, mutect2, varscan2
- C19orf12 | c.361C>T p.L121= (on ENST00000392278 / NM_001031726.3; = p.L110= on NM_031448.6) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV60365766; called by muse, mutect2, varscan2
- C1QTNF1 | c.714G>A p.L238= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100190164; called by muse, mutect2, varscan2
- C1QTNF6 | c.801C>A p.T267= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV55397419; called by muse, mutect2, varscan2
- C8orf82 | c.333G>A p.P111= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1276015057, COSV99430216; called by muse, mutect2, varscan2
- CACNA1I | c.243T>C p.F81= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100361262; called by muse, mutect2, varscan2
- CAVIN2 | c.1020G>A p.A340= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs761352584, COSV58423358; called by mutect2, varscan2
- CCDC116 | c.1287C>T p.N429= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV53039436, COSV99489458; called by muse, mutect2, varscan2
- CD46 | c.24G>A p.E8= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100523050; called by muse, mutect2, varscan2
- CDR1 | c.18C>T p.D6= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs975564173, COSV100983443; called by muse, mutect2, varscan2
- CFAP74 | c.2124C>T p.S708= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CHRNB4 | c.1008C>T p.C336= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99929540; called by muse, mutect2, varscan2
- CHSY1 | c.1150T>C p.L384= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99574172; called by muse, mutect2, varscan2
- CIBAR1 | c.570C>T p.I190= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs759670572, COSV63898390; called by muse, varscan2
- COLGALT2 | c.690C>T p.F230= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100730828; called by muse, mutect2
- CREB3 | c.36G>A p.L12= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV59213220; called by muse, mutect2, varscan2
- CRISP3 | c.690C>T p.D230= (on ENST00000371159 / NM_001368123.1; = p.D212= on NM_006061.4) | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs768358319, COSV99539161; called by muse, mutect2, varscan2
- CSRP1 | c.6G>A p.P2= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs754308439, COSV100384551; called by muse, mutect2, varscan2
- CWF19L2 | c.2448A>G p.R816= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99979698; called by muse, mutect2, varscan2
- CXCL12 | c.96C>T p.C32= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV100639028; called by muse, mutect2, varscan2
- DBP | c.174G>A p.L58= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1261324343, COSV99320822; called by muse, mutect2, varscan2
- DBX1 | c.765G>A p.L255= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1231804061, COSV99910298; called by muse, mutect2, varscan2
- DDR1 | c.1650T>G p.P550= (on ENST00000324771; = p.P513= on NM_001954.4) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100241961; called by muse, mutect2, varscan2
- DDX27 | c.873C>T p.R291= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs377733475; called by muse, varscan2
- DISP3 | c.435C>T p.S145= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99609661; called by muse, mutect2
- DMRTC2 | c.468G>T p.L156= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99523470; called by muse, mutect2, varscan2
- DNAH5 | c.8955C>A p.S2985= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99453038; called by muse, mutect2, varscan2
- DNAJB11 | c.354A>C p.G118= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV99408708; called by muse, mutect2, varscan2
- DROSHA | c.1230T>C p.P410= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100757784; called by muse, mutect2, varscan2
- EXOSC10 | c.84C>T p.G28= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100442795; called by muse, mutect2
- FGGY | c.858G>A p.T286= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs142638637; called by muse, mutect2, varscan2
- G2E3 | c.18T>C p.P6= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99249845; called by muse, mutect2, varscan2
- GPR4 | c.30C>T p.H10= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs199791684, COSV100547177; called by muse, mutect2, varscan2
- GRIN2C | c.114C>T p.S38= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99501338; called by muse, mutect2, varscan2
- GRM4 | c.2127G>A p.L709= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100946782; called by muse, mutect2, varscan2
- IFI16 | c.2010C>T p.S670= (on ENST00000295809 / NM_001364867.2; = p.S614= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs773070697, COSV55537157; called by muse, mutect2, varscan2
- IKBKE | c.300C>T p.S100= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1553384844, COSV100898373; called by muse, mutect2, varscan2
- IL6ST | c.2232T>C p.S744= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs138205220; called by muse, mutect2, varscan2
- IMPG2 | c.1395C>A p.A465= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99516249; called by muse, mutect2, varscan2
- INAVA | c.1299G>A p.V433= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100950095; called by muse, mutect2, varscan2
- ITIH2 | c.885T>C p.F295= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100623384; called by muse, mutect2, varscan2
- KIAA2013 | c.1530C>A p.S510= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100927147; called by muse, mutect2, varscan2
- KIF13A | c.4866G>A p.Q1622= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99437660; called by muse, mutect2, varscan2
- KIF1C | c.2500C>A p.R834= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100297279, COSV57906839; called by muse, mutect2, varscan2
- KMT2D | c.11220G>A p.Q3740= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1273756973, COSV99985102; called by muse, mutect2, varscan2
- KPNB1 | c.1587T>C p.Y529= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99268359; called by muse, mutect2, varscan2
- KRTAP2-4 | c.15C>T p.C5= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV101224342; called by muse, mutect2
- LARGE1 | c.321C>T p.G107= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV61675537; called by muse, mutect2, varscan2
- LRP11 | c.1323A>G p.G441= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1562436114, COSV99497889; called by muse, mutect2, varscan2
- MANBA | c.2382C>T p.C794= (on ENST00000642252; = p.C748= on NM_005908.4) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99899085; called by muse, mutect2, varscan2
- MAP3K11 | c.618C>T p.A206= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs766037928, COSV100482686; called by muse, mutect2, varscan2
- MC1R | c.612C>T p.A204= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs773313328, COSV59626517; called by mutect2, varscan2
- MDM1 | c.2088T>C p.A696= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100292039; called by muse, mutect2, varscan2
- MELK | c.1359T>C p.H453= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99974994; called by muse, mutect2, varscan2
- MPZ | c.546C>T p.C182= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100337949; called by muse, mutect2, varscan2
- MSGN1 | c.390C>T p.S130= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1286362309, COSV55263434; called by muse, mutect2, varscan2
- MUTYH | c.600T>C p.R200= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1322980057, COSV100588145; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO9A | c.6522T>C p.I2174= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100614146; called by muse, mutect2, varscan2
- NDC1 | c.1950T>C p.G650= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99323889; called by muse, mutect2, varscan2
- NEURL3 | c.99G>A p.T33= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100182486; called by muse, mutect2, varscan2
- NOTCH4 | c.15A>G p.S5= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs778415999, COSV100900931; called by muse, mutect2, varscan2
- NRK | c.3066T>C p.H1022= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99688900; called by muse, mutect2, varscan2
- OGFR | c.1797G>A p.S599= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs375765704, COSV51697008; called by muse, varscan2
- OR10G8 | c.561C>A p.A187= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV101461866, COSV70908582; called by muse, mutect2, varscan2
- OR2AK2 | c.120A>G p.T40= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100824273; called by muse, mutect2, varscan2
- PCDH19 | c.1644G>A p.T548= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs372952752, COSV55258437; ClinVar: benign; called by muse, mutect2, varscan2
- PCDHA4 | c.2193G>A p.A731= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs1229745044, COSV63543463; called by muse, mutect2, varscan2
- PCF11 | c.528T>C p.P176= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100019085; called by muse, mutect2, varscan2
- PCM1 | c.2658G>A p.T886= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs749508754, COSV61519853; called by muse, mutect2, varscan2
- PCM1 | c.3309G>A p.S1103= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs758884233, COSV61514530, COSV61516201; called by muse, mutect2, varscan2
- PPP1R13B | c.2103G>A p.A701= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs765077409, COSV52452973, COSV52453611; called by muse, mutect2, varscan2
- PTPRO | c.6G>A p.G2= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs745646041, COSV99841461; called by muse, mutect2, varscan2
- PTPRU | c.639G>A p.A213= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1245853977, COSV100113559; called by muse, mutect2
- RASA3 | c.2103G>A p.A701= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs200637546; called by muse, mutect2, varscan2
- RASSF5 | c.532C>A p.R178= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100795239; called by muse, mutect2, varscan2
- RDH8 | c.792C>T p.N264= (on ENST00000651512; = p.N244= on NM_015725.4) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV50674473; called by muse, mutect2, varscan2
- RHBG | c.198C>T p.D66= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs568339394, COSV54806062, COSV99659985; called by muse, mutect2, varscan2
- RHO | c.990C>T p.D330= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs548113513, COSV99960762; called by muse, mutect2, varscan2
- RREB1 | c.2841C>T p.D947= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100619752; called by muse, mutect2, varscan2
- SIGLEC10 | c.16C>T p.L6= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100219357, COSV59484480; called by muse, varscan2
- SIX6 | c.555G>A p.A185= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100576537; called by muse, mutect2
- SLC6A2 | c.1032G>A p.L344= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99574435; called by muse, mutect2, varscan2
- SLC7A4 | c.159G>A p.S53= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs749037092, COSV100298837; called by muse, mutect2, varscan2
- STRN4 | c.1377C>T p.D459= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs201109051, COSV99623948; called by muse, mutect2, varscan2
- TASOR2 | c.6411T>C p.D2137= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100050889; called by muse, mutect2, varscan2
- TECTA | c.2199C>T p.S733= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs397517145, COSV50699092; called by muse, mutect2, varscan2
- THAP12 | c.1977G>A p.P659= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs577884315, COSV99473214; called by muse, mutect2, varscan2
- TMC2 | c.2595G>A p.L865= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100727908; called by muse, mutect2, varscan2
- TRAV10 | c.9G>A p.K3= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- TRAV8-4 | c.312C>T p.D104= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs375215240; called by muse, mutect2, varscan2
- TTN | c.18654T>G p.S6218= (on ENST00000591111; = p.S5291= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100625947; called by muse, mutect2, varscan2
- UGT2B15 | c.1143C>A p.I381= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as COSV57733514, COSV57734277; called by muse, mutect2, varscan2
- UNC5B | c.2355C>T p.G785= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1411676226, COSV100101198; called by muse, mutect2, varscan2
- USP22 | c.826C>A p.R276= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99820445; called by muse, mutect2, varscan2
- USP36 | c.2580G>A p.L860= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100361751; called by muse, mutect2
- VPS13A | c.5247A>G p.S1749= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100653335; called by muse, mutect2, varscan2
- ZNF101 | c.96G>A p.V32= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100543615; called by muse, mutect2, varscan2
- ZNF462 | c.99A>G p.P33= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV99473007; called by muse, mutect2, varscan2
- ZNF700 | c.1179G>A p.K393= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs1315128855, COSV99583742; called by muse, mutect2, varscan2
- ZNF839 | c.1215T>C p.F405= (on ENST00000558850 / NM_001267827.1; = p.F521= on NM_018335.5) | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as COSV99216387; called by muse, mutect2, varscan2
- ZNRF4 | c.714C>T p.P238= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs376523858, COSV99706679; called by muse, mutect2, varscan2
- AK9 | c.3633+23del | Intron (DEL) | VAF 20/40 reads (50%) | catalogued as rs552385212; called by mutect2, varscan2
- AL109984.1 | n.186+1698del | Intron (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- AL136982.4 | n.126T>C | RNA (SNP) | VAF 116/466 reads (25%) | called by muse, mutect2, varscan2
- CLASP2 | c.1927+372C>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100224173; called by muse, mutect2, varscan2
- CTSL3P | n.429T>C | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- HLA-L | n.793C>T | RNA (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- KIAA0930 | c.853-930del | Intron (DEL) | VAF 15/23 reads (65%) | catalogued as rs764079139; called by mutect2, varscan2
- KIF2A | c.1647-1208C>T | Intron (SNP) | VAF 33/67 reads (49%) | catalogued as COSV66945494; called by muse, mutect2, varscan2
- KRT18P55 | n.800G>A | RNA (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- MIR1283-2 | n.37T>A | RNA (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- MIR34A | n.70G>A | RNA (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2234T>C | Intron (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- RAB18 | c.68+642A>G | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- SLC48A1 | c.*13G>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99316778; called by muse, mutect2, varscan2
- TAF8 | chr6:42048630 ins C | 5'Flank (INS) | VAF 14/29 reads (48%) | catalogued as rs751989766; called by mutect2, varscan2
- TRNAU1AP | chr1:28580429 G>A | 3'Flank (SNP) | VAF 21/47 reads (45%) | catalogued as rs751753027; called by muse, mutect2, varscan2
